Somatic mutation profile of tumor specimen TCGA-50-5930-01A (aliquot TCGA-50-5930-01A-11D-1753-08) from TCGA case TCGA-50-5930, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.2 years (17,238 days).
Specimen TCGA-50-5930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d1b211f-2212-49d0-8654-4550aefb9e59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5930-11A (Solid Tissue Normal), aliquot TCGA-50-5930-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3d61acb-c135-4631-acec-8d4031093a70

The open-access MAF lists 1,193 somatic variants for this specimen: 907 protein-altering or splice-affecting, 258 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 773, Silent 258, Nonsense Mutation 72, Splice Site 22, Frame Shift Del 18, Splice Region 9, Frame Shift Ins 8, Intron 7, RNA 6, 5'UTR 5, 3'UTR 4, 5'Flank 4.

Variants (750 of 1,193; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1906G>C p.G636R (on ENST00000288602 / NM_001374244.1; = p.G596R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs121913361, COSV56066561, COSV56185580, COSV56316158, COSV99954791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABAT | c.1229A>T p.H410L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV51621698; called by muse, mutect2, varscan2
- ABCA5 | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV67016238; called by muse, mutect2, varscan2
- ABCC8 | c.3889A>G p.M1297V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56848054; called by muse, mutect2, varscan2
- ABCF1 | c.2363A>G p.Y788C (on ENST00000326195 / NM_001025091.2; = p.Y750C on NM_001090.3) | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV58228498; called by muse, mutect2, varscan2
- ABI3BP | c.2614G>A p.G872R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52532151; called by muse, mutect2, varscan2
- ABL2 | c.2328G>T p.K776N (on ENST00000502732 / NM_007314.4; = p.K761N on NM_005158.5) | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61012289; called by muse, mutect2, varscan2
- ABLIM2 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56402007, COSV56404504; called by muse, mutect2, varscan2
- ACCSL | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66580732; called by muse, mutect2, varscan2
- ACHE | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476211897, COSV53816340, COSV99574090; called by muse, mutect2, varscan2
- ACOT4 | c.972G>T p.Q324H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV58335550, COSV58336370; called by muse, mutect2, varscan2
- ACOXL | c.988G>T p.G330W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67734827; called by muse, mutect2, varscan2
- ACP3 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV60485239; called by muse, mutect2, varscan2
- ACSF3 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58077481; called by muse, mutect2, varscan2
- ACTL7B | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV65927112; called by muse, mutect2, varscan2
- ADAM12 | c.830A>G p.Q277R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64104290; called by muse, mutect2, varscan2
- ADAM23 | c.2078G>C p.S693T | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.324); catalogued as COSV52211207; called by muse, mutect2, varscan2
- ADAMTS12 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 23/178 reads (13%) | catalogued as COSV61259417; called by muse, mutect2, varscan2
- ADAMTS4 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV63489614; called by muse, mutect2, varscan2
- ADAMTS6 | c.2207T>G p.V736G | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.767); catalogued as COSV66858265; called by muse, mutect2, varscan2
- ADAMTS6 | c.1916G>T p.W639L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV66858271; called by muse, mutect2, varscan2
- ADAMTS9 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 55/144 reads (38%) | catalogued as COSV55777721, COSV99899601; called by muse, mutect2, varscan2
- ADAMTSL3 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54441783; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2787del p.V930* | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | catalogued as COSV54461149; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.5005G>T p.V1669L | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV54441817; called by muse, mutect2, varscan2
- ADCY7 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54265437; called by muse, mutect2, varscan2
- ADGRB1 | c.2476G>T p.V826L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV60093919; called by muse, mutect2
- ADGRF4 | c.1693C>G p.P565A | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51950777; called by muse, mutect2, varscan2
- ADGRG5 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV61082894; called by muse, mutect2, varscan2
- ADGRL3 | c.2078A>G p.Q693R (on ENST00000506720 / NM_001322402.2; = p.Q625R on NM_015236.6) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV72230069; called by muse, mutect2, varscan2
- ADH1B | c.568-2A>T p.X190_splice | Splice Site (SNP) | VAF 50/139 reads (36%) | catalogued as COSV59295766; called by muse, mutect2, varscan2
- ADIPOQ | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57858745; called by muse, mutect2, varscan2
- AEBP1 | c.2854C>A p.R952S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as rs996412633, COSV56255652, COSV56256532; called by muse, mutect2, varscan2
- AFF2 | c.2441C>A p.P814H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53982874; called by muse, mutect2, varscan2
- AGMO | c.52A>T p.M18L | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV61108995, COSV61113509; called by muse, mutect2, varscan2
- AGTR2 | c.415A>G p.S139G | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64156287; called by muse, mutect2, varscan2
- AHNAK2 | c.15591G>T p.M5197I | Missense Mutation (SNP) | VAF 135/361 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV60911552; called by muse, mutect2, varscan2
- AHNAK2 | c.10425G>A p.M3475I | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV60911562; called by muse, mutect2, varscan2
- AK9 | c.841A>T p.M281L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV53420652; called by muse, mutect2
- AKAP13 | c.2956G>T p.A986S | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs1012670194, COSV63452508; called by muse, mutect2, varscan2
- AKAP9 | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV62342229; called by muse, mutect2, varscan2
- AL592490.1 | c.1255G>C p.V419L | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV69425393; called by muse, mutect2, varscan2
- ALK | c.4270C>A p.L1424I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV66562770; called by muse, mutect2, varscan2
- ALK | c.2258G>T p.R753L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs187200776, COSV66562776, COSV66585781; called by muse, mutect2, varscan2
- ALK | c.1698G>T p.L566F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV66562784, COSV66595451; called by muse, mutect2, varscan2
- ALPP | c.282C>G p.D94E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.432); catalogued as rs761489650, COSV67396016; called by muse, mutect2
- ANKRD12 | c.1448A>T p.K483I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV50821132; called by muse, mutect2, varscan2
- ANKRD17 | c.3415G>T p.G1139C | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV58217920; called by muse, mutect2, varscan2
- ANKRD17 | c.2783G>C p.R928P | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.415); catalogued as COSV58217928, COSV58220156, COSV58229041; called by muse, mutect2, varscan2
- ANKS1B | c.3245A>T p.Q1082L (on ENST00000547776 / NM_152788.4; = p.Q248L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59116785; called by muse, mutect2, varscan2
- ANO5 | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs886042583, COSV61083507; called by muse, mutect2, varscan2
- AOC2 | c.1183G>T p.G395* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV53198601; called by muse, mutect2, varscan2
- AP4E1 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as rs1282600988, COSV55916062; called by muse, mutect2, varscan2
- APC | c.2447C>T p.T816I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1410017491, COSV57334123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APCS | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV54817515, COSV54817666; called by muse, mutect2, varscan2
- APOB | c.12792T>A p.D4264E | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV51929656; called by muse, mutect2, varscan2
- APOBEC3D | c.292T>A p.F98I | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53326191; called by muse, mutect2, varscan2
- APOBR | c.2935C>A p.L979I (on ENST00000431282; = p.L988I on NM_018690.4) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV60489647; called by muse, mutect2
- APOD | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV58401557; called by muse, mutect2, varscan2
- ARHGAP33 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); catalogued as COSV50120490; called by muse, mutect2, varscan2
- ARMC3 | c.2572C>A p.L858M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53059111; called by muse, mutect2, varscan2
- ARSI | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV60817075; called by muse, mutect2, varscan2
- ASB3 | c.1106G>T p.C369F | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV55074835; called by muse, mutect2, varscan2
- ASPHD1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV58098331; called by muse, mutect2, varscan2
- ASTN2 | c.1438G>T p.V480L (on ENST00000313400 / NM_001365069.1; = p.V429L on NM_014010.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV57764680; called by muse, mutect2, varscan2
- ATG4D | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100521146, COSV58762294; called by muse, varscan2
- ATP23 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV55685694; called by muse, mutect2, varscan2
- ATP2B3 | c.1373T>A p.L458Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54843293; called by muse, mutect2, varscan2
- ATP6V1C1 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV67777672; called by muse, mutect2, varscan2
- ATP7B | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.127); catalogued as COSV54436762; called by muse, mutect2, varscan2
- AXIN1 | c.2371G>T p.G791W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51985484, COSV99249313; called by muse, mutect2, varscan2
- B4GALT6 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV52703055, COSV52704310; called by muse, mutect2, varscan2
- BAIAP3 | c.1923G>T p.E641D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV50103791; called by muse, mutect2, varscan2
- BCAT1 | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as COSV53909279; called by muse, mutect2, varscan2
- BCL2L11 | c.254G>T p.R85I | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV58028616; called by muse, mutect2, varscan2
- BCL2L11 | c.563G>T p.R188L (on ENST00000393256 / NM_138621.5; = p.R128L on NM_006538.5) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV58028638; called by muse, mutect2, varscan2
- BCO1 | c.191A>T p.D64V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV50728725; called by muse, mutect2, varscan2
- BEND5 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65716809; called by muse, mutect2
- BEST1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1514198, COSV56444889; called by muse, mutect2
- BEST2 | c.205T>G p.C69G | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV50361120; called by muse, mutect2, varscan2
- BIRC6 | c.3755A>C p.Q1252P | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV70197302; called by muse, mutect2, varscan2
- BMP2K | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58593331; called by muse, mutect2, varscan2
- BSN | c.5735G>T p.S1912I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56515190; called by muse, mutect2, varscan2
- BTD | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as CM070656, COSV57728772; called by muse, mutect2, varscan2
- C10orf62 | c.591C>G p.H197Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV65705125; called by muse, mutect2, varscan2
- C12orf40 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61130669; called by muse, mutect2, varscan2
- C12orf57 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV57546610; called by muse, mutect2, varscan2
- C12orf65 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53515972; called by muse, mutect2, varscan2
- C12orf66 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.077); catalogued as COSV61322767; called by muse, mutect2
- C1QTNF3 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.386); catalogued as rs768912465, COSV51468061; called by muse, mutect2, varscan2
- C20orf194 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.509); catalogued as COSV52693736; called by muse, mutect2, varscan2
- C6 | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV54707733; called by muse, mutect2
- C6orf118 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV57813770; called by muse, mutect2, varscan2
- C7 | c.2090A>T p.Q697L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1271220678, COSV57472606; called by muse, mutect2, varscan2
- C9orf153 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59250959; called by muse, mutect2, varscan2
- CACNA1I | c.5598C>G p.I1866M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV60804112; called by muse, mutect2, varscan2
- CACNA2D1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs867664615; called by mutect2, varscan2
- CACNB1 | c.629-1G>T p.X210_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV59998420; called by muse, mutect2, varscan2
- CALML5 | c.75C>A p.N25K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV66702453; called by muse, mutect2, varscan2
- CAMK2N1 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66757367; called by muse, mutect2, varscan2
- CAMKV | c.1502G>T p.S501I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as COSV56554705; called by muse, mutect2, varscan2
- CAMSAP2 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52668737; called by muse, mutect2
- CAMTA1 | c.4465C>A p.L1489I | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.222); catalogued as COSV57890855; called by muse, mutect2, varscan2
- CAPG | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55706897; called by muse, mutect2, varscan2
- CAPRIN1 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.728); catalogued as rs11552285, COSV58218962; called by muse, mutect2, varscan2
- CASD1 | c.2325G>T p.L775F | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV51971526; called by muse, mutect2, varscan2
- CASKIN1 | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV58871113; called by muse, mutect2, varscan2
- CASP5 | c.546C>A p.I182= | Splice Region (SNP) | VAF 19/99 reads (19%) | catalogued as rs1455955135, COSV52827591; called by muse, mutect2, varscan2
- CAV3 | c.24T>A p.D8E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV59561566; called by muse, mutect2, varscan2
- CBLL2 | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV60368692; called by muse, mutect2, varscan2
- CBX8 | c.980A>G p.Q327R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV53935902; called by muse, mutect2
- CC2D1B | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV52559509; called by muse, mutect2
- CCBE1 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV67949527; called by muse, mutect2, varscan2
- CCDC116 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs1018824216, COSV53039929; called by muse, mutect2
- CCDC150 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV55873180; called by muse, mutect2, varscan2
- CCDC38 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV60182666; called by muse, mutect2, varscan2
- CCDC89 | c.725A>T p.Q242L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV57033741; called by muse, mutect2, varscan2
- CCL7 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52336785; called by muse, mutect2, varscan2
- CCM2L | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52949245, COSV52949570; called by muse, mutect2, varscan2
- CCNO | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV57004477; called by muse, mutect2, varscan2
- CD101 | c.1831C>G p.Q611E | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV56717082; called by muse, mutect2, varscan2
- CD163 | c.2491A>C p.S831R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.259); catalogued as COSV63130778; called by muse, mutect2, varscan2
- CD163 | c.1198A>G p.R400G | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.187); catalogued as COSV63130789; called by muse, mutect2, varscan2
- CD300C | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58169930; called by muse, mutect2
- CD4 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV50589861, COSV99163992; called by mutect2, varscan2
- CDC7 | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV52310044; called by muse, mutect2, varscan2
- CDH11 | c.2263C>A p.L755M | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51756332; called by muse, mutect2, varscan2
- CDH11 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV51756347; called by muse, mutect2
- CDH4 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848531, COSV64647760; called by muse, mutect2, varscan2
- CDK12 | c.1313A>G p.K438R | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV70999922; called by muse, mutect2, varscan2
- CDK15 | c.312G>T p.L104F (on ENST00000652192 / NM_001366386.2; = p.L53F on NM_139158.2) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV53632631; called by muse, mutect2, varscan2
- CDK15 | c.885G>T p.Q295H (on ENST00000652192 / NM_001366386.2; = p.Q244H on NM_139158.2) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV53632652; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV62573211, COSV62573947; called by muse, mutect2, varscan2
- CDRT1 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63052738; called by muse, mutect2, varscan2
- CELA1 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV53329366; called by muse, mutect2
- CEP126 | c.2756C>T p.P919L | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.147); catalogued as rs370774279; called by muse, mutect2, varscan2
- CES5A | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51865156; called by muse, mutect2, varscan2
- CFAP91 | c.464A>T p.Q155L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV56340100; called by muse, mutect2, varscan2
- CHD9 | c.4070G>T p.R1357L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV54607877, COSV54608971; called by muse, mutect2, varscan2
- CHRDL1 | c.1222A>T p.S408C (on ENST00000372045; = p.S414C on NM_145234.4) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV54324009; called by muse, mutect2, varscan2
- CHRDL2 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565153434, COSV55222215; called by muse, mutect2, varscan2
- CHST1 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV57322839, COSV57326103; called by muse, mutect2, varscan2
- CLCN1 | c.2881G>C p.G961R | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.532); catalogued as COSV58368616, COSV58369626; called by muse, mutect2, varscan2
- CLCN7 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51969582; called by muse, mutect2
- CLDN16 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53227357; called by muse, mutect2, varscan2
- CMTR2 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57602383; called by muse, mutect2, varscan2
- CNTN1 | c.2009A>T p.D670V | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61638036; called by muse, mutect2, varscan2
- CNTN6 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV63166753; called by muse, mutect2, varscan2
- CNTNAP4 | c.1841G>A p.S614N | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV56672482; called by muse, mutect2, varscan2
- COL11A1 | c.3403G>T p.G1135* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | catalogued as COSV62177707; called by muse, mutect2, varscan2
- COL11A1 | c.2296-2A>G p.X766_splice | Splice Site (SNP) | VAF 28/158 reads (18%) | catalogued as COSV62177715; called by muse, mutect2, varscan2
- COL11A1 | c.249T>A p.S83R | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62177719; called by muse, mutect2, varscan2
- COL11A2 | c.2602G>T p.G868C (on ENST00000341947 / NM_080680.3; = p.G761C on NM_080679.2) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59494993; called by muse, mutect2, varscan2
- COL12A1 | c.7634G>T p.G2545V | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59392526; called by muse, mutect2, varscan2
- COL1A2 | c.2225G>T p.G742V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51955484; called by muse, mutect2, varscan2
- COL20A1 | c.2716C>G p.R906G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58914276; called by muse, mutect2, varscan2
- COL25A1 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67648256; called by muse, mutect2, varscan2
- COL27A1 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61924064; called by muse, mutect2
- COL28A1 | c.1422G>T p.Q474H | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.864); catalogued as COSV68081364; called by muse, mutect2, varscan2
- COL3A1 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58584925, COSV58589118; called by muse, mutect2, varscan2
- COL4A2 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.187); catalogued as COSV64626605; called by muse, mutect2, varscan2
- COL8A1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV53731656; called by muse, mutect2, varscan2
- COL9A1 | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014122856, COSV57881467; called by muse, mutect2, varscan2
- CORO1C | c.926G>T p.S309I | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.71); catalogued as COSV54594587, COSV54594856; called by muse, mutect2, varscan2
- CPED1 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV59999458; called by muse, mutect2, varscan2
- CPNE4 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV70192505; called by muse, mutect2, varscan2
- CPNE8 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58840668; called by muse, mutect2, varscan2
- CREBRF | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51632206; called by muse, mutect2, varscan2
- CRMP1 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV61479011; called by muse, mutect2, varscan2
- CRTC3 | c.1819G>T p.D607Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51595396; called by muse, mutect2, varscan2
- CRYGA | c.39G>T p.Q13H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58016114; called by muse, mutect2, varscan2
- CRYL1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV53417410; called by muse, mutect2, varscan2
- CSMD2 | c.2960C>A p.T987N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV53896442; called by muse, mutect2, varscan2
- CSRNP3 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV58776731; called by muse, mutect2, varscan2
- CUTC | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV65081654; called by muse, mutect2, varscan2
- CYP26B1 | c.230G>T p.R77M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV50011251; called by muse, mutect2, varscan2
- CYSLTR1 | c.594T>A p.F198L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64819742; called by muse, varscan2
- DACT1 | c.1414G>T p.G472W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV60020038; called by muse, mutect2, varscan2
- DCAF4L2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs865992251, COSV60477474, COSV60477956; called by muse, mutect2, varscan2
- DCDC1 | c.1749C>A p.Y583* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as COSV60838206; called by muse, mutect2, varscan2
- DCSTAMP | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV52576915; called by muse, mutect2, varscan2
- DCT | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65468238, COSV65468438; called by muse, mutect2, varscan2
- DDI1 | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV56372656; called by muse, mutect2, varscan2
- DDRGK1 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV63226659; called by muse, mutect2, varscan2
- DDX4 | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61754388; called by muse, mutect2, varscan2
- DENND2B | c.2173-2A>T p.X725_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV58202360; called by muse, mutect2, varscan2
- DEUP1 | c.1172C>A p.A391D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53210918; called by mutect2, varscan2
- DGKH | c.2680A>T p.R894W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54929751; called by muse, mutect2, varscan2
- DGKH | c.3350G>C p.C1117S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV54929765; called by muse, mutect2, varscan2
- DGKI | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 41/219 reads (19%) | catalogued as COSV55943167; called by muse, mutect2, varscan2
- DHX34 | c.3298G>T p.G1100W | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV60894841; called by muse, mutect2, varscan2
- DHX9 | c.3644G>T p.G1215V | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62358829; called by muse, mutect2, varscan2
- DICER1 | c.4669A>G p.K1557E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58617281; called by muse, mutect2, varscan2
- DLG5 | c.3634G>A p.A1212T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV64947342; called by muse, mutect2, varscan2
- DLGAP1 | c.2604G>T p.Q868H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59794512; called by muse, mutect2, varscan2
- DLST | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV53165830; called by muse, mutect2, varscan2
- DMRTC2 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54186231, COSV54188429; called by muse, mutect2, varscan2
- DNAH9 | c.4331G>T p.W1444L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52342699; called by muse, mutect2, varscan2
- DNER | c.1040G>A p.C347Y | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753250384, COSV59162923; called by muse, mutect2, varscan2
- DNMT3B | c.779G>C p.W260S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52416434; called by muse, mutect2, varscan2
- DOP1B | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as rs1488120917, COSV67692722; called by muse, mutect2, varscan2
- DPYD | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV64593938; called by muse, mutect2, varscan2
- DSG3 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 31/180 reads (17%) | catalogued as COSV57124458, COSV57125106; called by muse, mutect2, varscan2
- DYNAP | c.157C>G p.Q53E (on ENST00000321600; = p.Q27E on NM_173629.3) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV58666164; called by muse, mutect2, varscan2
- ECI2 | c.532G>T p.A178S (on ENST00000380118 / NM_206836.3; = p.A148S on NM_006117.2) | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as COSV60985723; called by muse, mutect2, varscan2
- EDAR | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV51501332; called by muse, mutect2, varscan2
- EDNRB | c.982A>G p.I328V (on ENST00000377211 / NM_001201397.1; = p.I238V on NM_000115.5) | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.018); catalogued as rs767943900, COSV57520522; called by muse, mutect2, varscan2
- EFCAB12 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.723); catalogued as COSV58175461, COSV58178531; called by muse, mutect2
- EFCC1 | c.1663G>T p.G555* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV71401815; called by muse, mutect2, varscan2
- EFS | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53731664; called by muse, mutect2, varscan2
- ELL2 | c.1016A>T p.H339L | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52981762; called by muse, mutect2, varscan2
- ELOA2 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.24); catalogued as COSV55296253; called by muse, mutect2, varscan2
- ELP6 | c.776A>T p.K259I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV56131914; called by muse, mutect2, varscan2
- EMC6 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs202001960, COSV50265012; called by muse, mutect2, varscan2
- ENC1 | c.1088C>G p.T363S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.369); catalogued as COSV56628952, COSV56629110; called by muse, mutect2, varscan2
- ENO2 | c.544A>C p.M182L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.034); catalogued as COSV50387532; called by muse, mutect2, varscan2
- ENO3 | c.318T>A p.F106L | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.091); catalogued as COSV56697388; called by muse, mutect2, varscan2
- ENOSF1 | c.910G>T p.D304Y (on ENST00000340116 / NM_001354066.2; = p.D256Y on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51891550, COSV51892930; called by muse, mutect2, varscan2
- ENPEP | c.1644C>A p.N548K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV54448664; called by muse, mutect2, varscan2
- ENPP3 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV62953620; called by muse, mutect2, varscan2
- EP400 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs199695029; called by muse, mutect2, varscan2
- EPAS1 | c.95A>T p.E32V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55385308; called by muse, mutect2, varscan2
- EPHA3 | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60699447, COSV60707218, COSV60708573; called by muse, mutect2, varscan2
- EPHB3 | c.1255A>G p.T419A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.341); catalogued as rs951062210, COSV57805082; called by muse, mutect2
- EPHB3 | c.2332G>T p.G778C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57805090; called by muse, mutect2, varscan2
- EPHX3 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.603); catalogued as COSV55654966; called by muse, mutect2, varscan2
- EPN2 | c.206A>C p.K69T | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59060566; called by muse, mutect2, varscan2
- ERF | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as CM142386, COSV55895364; called by muse, mutect2, varscan2
- ERN2 | c.263del p.G88Afs*14 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as COSV99890600; called by mutect2, pindel, varscan2
- EVC2 | c.1413G>C p.Q471H | Missense Mutation (SNP) | VAF 113/355 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60390416; called by muse, mutect2, varscan2
- EVI2B | c.848T>C p.L283S | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV58363611; called by muse, mutect2, varscan2
- EXO1 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as COSV62216995; called by muse, mutect2
- FAF1 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV65637461; called by muse, mutect2, varscan2
- FAM135B | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52714798; called by muse, mutect2, varscan2
- FAM13C | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV53245798, COSV53247716; called by muse, mutect2, varscan2
- FAM171B | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.005); catalogued as rs140891434; called by mutect2, varscan2
- FAS | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 92/636 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58238397; called by muse, mutect2, varscan2
- FASTKD1 | c.1577A>T p.H526L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV71624175; called by muse, mutect2, varscan2
- FAT3 | c.4822G>C p.G1608R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53080488, COSV53092479; called by muse, varscan2
- FBN2 | c.4577C>A p.T1526K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV52503613; called by muse, mutect2, varscan2
- FBN2 | c.745C>G p.H249D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV52503656; called by muse, mutect2, varscan2
- FBXL17 | c.2072G>T p.G691V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV62850970; called by muse, mutect2, varscan2
- FBXL4 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57745895; called by muse, mutect2, varscan2
- FBXO3 | c.1063A>T p.I355F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV55765678, COSV99682148; called by muse, mutect2, varscan2
- FCRL1 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63824560, COSV63826164; called by muse, mutect2, varscan2
- FER1L6 | c.3148G>T p.E1050* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV67549010; called by muse, mutect2
- FFAR3 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV100588325; called by mutect2, varscan2
- FGD6 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.058); catalogued as COSV59691667; called by muse, mutect2, varscan2
- FGF14 | c.451del p.E151Kfs*5 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as COSV65939056; called by mutect2, pindel, varscan2
- FGF18 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51125801; called by muse, mutect2, varscan2
- FHL5 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV58736594; called by muse, mutect2
- FLG | c.3320C>G p.S1107* | Nonsense Mutation (SNP) | VAF 144/414 reads (35%) | catalogued as COSV64239300; called by muse, mutect2, varscan2
- FLG | c.2512C>A p.Q838K | Missense Mutation (SNP) | VAF 148/453 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV64239306; called by muse, mutect2, varscan2
- FOXB2 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV65022686; called by muse, mutect2, varscan2
- FRMD3 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV58458650; called by muse, mutect2, varscan2
- FSIP2 | c.17675C>A p.P5892H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100553773; called by muse, mutect2, varscan2
- FSTL5 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV60187074; called by muse, mutect2, varscan2
- GABRA5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 23/115 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV100165950, COSV59477667; called by muse, mutect2, varscan2
- GABRB2 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.023); catalogued as COSV50905836; called by muse, mutect2
- GABRG1 | c.998T>C p.M333T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54951715; called by muse, mutect2, varscan2
- GALK2 | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV59100416; called by muse, mutect2, varscan2
- GC | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as COSV56736499; called by muse, mutect2, varscan2
- GCLC | c.789G>T p.E263D (on ENST00000643939; = p.E261D on NM_001498.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV57594216; called by muse, mutect2, varscan2
- GDF5 | c.508C>G p.H170D | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65500348; called by muse, mutect2, varscan2
- GDNF | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58478894; called by muse, mutect2, varscan2
- GIMAP1-GIMAP5 | c.402+1G>T p.X134_splice | Splice Site (SNP) | VAF 11/85 reads (13%) | catalogued as COSV56187609, COSV56189115; called by muse, mutect2, varscan2
- GLI2 | c.3499C>A p.P1167T (on ENST00000361492 / NM_001374353.1; = p.P1184T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV58038046; called by muse, mutect2, varscan2
- GLIPR1L1 | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1220678947, COSV56881127; called by muse, mutect2
- GLIS1 | c.34T>G p.C12G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as COSV56546395; called by muse, mutect2, varscan2
- GLRA4 | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65455459; called by muse, mutect2, varscan2
- GLYAT | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 22/145 reads (15%) | catalogued as COSV53538820; called by muse, mutect2, varscan2
- GNA14 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59021534; called by muse, mutect2, varscan2
- GOLGB1 | c.7307A>G p.D2436G | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1236758291, COSV61463586; called by muse, mutect2, varscan2
- GOLGB1 | c.5399A>T p.Q1800L | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV61463591; called by muse, mutect2, varscan2
- GPALPP1 | c.752A>G p.H251R | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62705572; called by muse, mutect2, varscan2
- GPC2 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV52784634; called by muse, mutect2, varscan2
- GPC6 | c.1603G>T p.G535C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65504944; called by muse, mutect2, varscan2
- GPR158 | c.1489G>C p.G497R | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66275590; called by muse, mutect2, varscan2
- GPR158 | c.2867C>G p.P956R | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV66267587; called by muse, mutect2, varscan2
- GPR158 | c.3366dup p.K1123Qfs*10 | Frame Shift Ins (INS) | VAF 16/81 reads (20%) | catalogued as rs771672605; called by mutect2, pindel, varscan2
- GPR22 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51746481, COSV51763995; called by muse, mutect2, varscan2
- GPRIN1 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs372343847; called by muse, mutect2
- GRAP2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs201778964, COSV59994454; called by muse, mutect2, varscan2
- GRHL3 | c.794C>T p.T265I (on ENST00000350501 / NM_198174.3; = p.T270I on NM_021180.3) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); catalogued as COSV52565421, COSV52566992; called by muse, mutect2, varscan2
- GRIK2 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV59724596, COSV59743395; called by muse, mutect2, varscan2
- GRIK4 | c.1900T>A p.S634T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70801144; called by muse, mutect2, varscan2
- GRIP1 | c.1599A>T p.E533D (on ENST00000359742 / NM_001379345.1; = p.E481D on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as COSV54019396; called by muse, mutect2, varscan2
- GRK1 | c.702T>A p.G234= | Splice Region (SNP) | VAF 22/247 reads (9%) | catalogued as COSV59552208; called by muse, mutect2
- GUCY1A2 | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.135); catalogued as COSV56482456; called by muse, mutect2, varscan2
- HAL | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766606716, COSV54117138; called by muse, mutect2, varscan2
- HAP1 | c.1127A>T p.N376I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV57877926; called by muse, mutect2, varscan2
- HAPLN3 | c.1079A>T p.H360L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV61358315; called by muse, mutect2, varscan2
- HARBI1 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV58705728; called by muse, mutect2, varscan2
- HCN3 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64233587; called by muse, mutect2, varscan2
- HDX | c.1086C>A p.D362E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52974708; called by muse, mutect2, varscan2
- HECTD2 | c.822-2A>C p.X274_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | catalogued as COSV99979099; called by muse, mutect2, varscan2
- HEPHL1 | c.2492C>G p.A831G | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59890643; called by muse, mutect2, varscan2
- HFM1 | c.3184G>T p.A1062S | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV54024597; called by muse, mutect2
- HJV | c.342G>T p.M114I (on ENST00000336751 / NM_213653.4; = p.M1? on NM_145277.5) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV60951589; called by muse, mutect2, varscan2
- HOMEZ | c.82A>T p.N28Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV62536675; called by muse, mutect2
- HOXD13 | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66832446; called by muse, mutect2, varscan2
- HOXD4 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); catalogued as COSV60459601; called by muse, mutect2
- HSD3B2 | c.1022C>A p.P341Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM081307, COSV65592902; called by muse, varscan2
- HTR1A | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1029046608, COSV60500300; called by muse, mutect2, varscan2
- HTT | c.9143C>T p.P3048L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61859639; called by muse, mutect2, varscan2
- HUWE1 | c.6937G>T p.V2313L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV53339813; called by muse, mutect2, varscan2
- HYDIN | c.10165G>A p.G3389R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1482789426, COSV101158164; called by muse, mutect2, varscan2
- ICE1 | c.3889G>T p.E1297* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV56821720, COSV56826851; called by muse, mutect2, varscan2
- IER5 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs778831099, COSV62536996; called by muse, mutect2, varscan2
- IFNA7 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV53330526; called by muse, mutect2, varscan2
- IGDCC4 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61536073; called by muse, mutect2, varscan2
- IGF1 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61032093; called by mutect2, varscan2
- IGF2R | c.4002C>A p.D1334E | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV63627788; called by muse, mutect2, varscan2
- IGHV2-70 | c.219T>A p.D73E | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs181059057; called by muse, mutect2, varscan2
- IGHV3-30 | c.181G>C p.G61R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.433); catalogued as rs1286440461; called by muse, mutect2, varscan2
- IGLV3-10 | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368412336; called by muse, mutect2, varscan2
- IGLV9-49 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs970074292; called by muse, mutect2, varscan2
- IGSF1 | c.2716C>A p.L906I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63836781; called by muse, mutect2, varscan2
- IGSF10 | c.4574C>A p.S1525Y | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV56783208, COSV56786913, COSV56792681; called by muse, mutect2, varscan2
- IGSF10 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV56783215; called by muse, mutect2, varscan2
- IL18R1 | c.166T>G p.W56G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52123706; called by muse, mutect2
- IL18R1 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52122913, COSV52126993; called by muse, mutect2
- IL18R1 | c.577G>T p.G193* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV52123722; called by muse, mutect2, varscan2
- IL18RAP | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV51825115; called by muse, mutect2, varscan2
- IL1RN | c.202G>T p.E68* (on ENST00000409930 / NM_173842.3; = p.E50* on NM_000577.5) | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV52080232; called by muse, mutect2, varscan2
- INPPL1 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53354332, COSV53357714; called by muse, mutect2, varscan2
- IQGAP2 | c.944_945insA p.E316Gfs*3 | Frame Shift Ins (INS) | VAF 7/44 reads (16%) | catalogued as COSV99169293; called by mutect2, pindel, varscan2
- IRF4 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV66704728; called by muse, mutect2, varscan2
- ITGA4 | c.1480G>C p.V494L | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.705); catalogued as COSV51998972; called by muse, mutect2, varscan2
- ITIH2 | c.2005T>A p.W669R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV64432576; called by muse, mutect2, varscan2
- ITPRID2 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.996); catalogued as COSV57470451; called by muse, mutect2, varscan2
- IZUMO1R | c.508C>A p.H170N (on ENST00000440961; = p.H177N on NM_001199206.3) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.138); catalogued as COSV60622384; called by muse, mutect2, varscan2
- JARID2 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as COSV59184697, COSV59187338, COSV59192258; called by muse, mutect2, varscan2
- JARID2 | c.2228A>T p.N743I | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59187346; called by muse, mutect2, varscan2
- JPH1 | c.1708G>T p.G570C | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.337); catalogued as COSV60609833; called by muse, mutect2, varscan2
- KCNB2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs765031655, COSV73049534, COSV99074163; called by muse, mutect2, varscan2
- KCNC4 | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV63925373; called by muse, mutect2, varscan2
- KCND2 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 33/168 reads (20%) | catalogued as COSV58574269; called by muse, mutect2, varscan2
- KCNG1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV65368616; called by muse, mutect2, varscan2
- KCNH1 | c.1604G>A p.R535Q (on ENST00000271751 / NM_172362.3; = p.R508Q on NM_002238.4) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55075144; called by muse, mutect2, varscan2
- KCNH7 | c.3393T>A p.H1131Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.201); catalogued as COSV59791769; called by muse, mutect2, varscan2
- KCNJ3 | c.1290G>T p.L430F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV54530895; called by muse, varscan2
- KCNK10 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757458362, COSV56641566; called by muse, mutect2, varscan2
- KCNT2 | c.2611G>T p.G871C | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54071938, COSV54102577; called by muse, mutect2, varscan2
- KCNT2 | c.2015C>A p.P672Q | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99655700; called by muse, mutect2
- KCNV1 | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52085385; called by muse, mutect2, varscan2
- KDM4A | c.2570A>T p.H857L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64959146; called by muse, mutect2, varscan2
- KHDC3L | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as COSV64869015; called by muse, mutect2, varscan2
- KIAA0100 | c.1513-1G>C p.X505_splice | Splice Site (SNP) | VAF 22/48 reads (46%) | catalogued as COSV66491534, COSV66494883; called by muse, mutect2, varscan2
- KIAA1109 | c.7329G>T p.K2443N | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV52666990; called by muse, mutect2, varscan2
- KIAA1210 | c.3232G>A p.A1078T | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.127); catalogued as rs1482865497, COSV68175649; called by muse, mutect2, varscan2
- KIAA1549 | c.5826G>T p.Q1942H (on ENST00000422774 / NM_001164665.2; = p.Q1926H on NM_020910.3) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54309521; called by muse, mutect2, varscan2
- KIAA1614 | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV62550623, COSV62551403; called by muse, mutect2, varscan2
- KIF16B | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.784); catalogued as COSV61703739; called by muse, mutect2, varscan2
- KIF23 | c.1005G>T p.L335F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52978393; called by muse, mutect2, varscan2
- KIF27 | c.1902A>T p.Q634H | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV52826396; called by muse, mutect2, varscan2
- KIF2B | c.1534T>G p.S512A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV52128734, COSV52129862; called by muse, mutect2, varscan2
- KITLG | c.342C>G p.C114W | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57200673; called by muse, mutect2, varscan2
- KL | c.1467G>T p.L489F | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.285); catalogued as COSV66308291; called by muse, mutect2, varscan2
- KLHL32 | c.866A>T p.D289V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs757907292, COSV65111358; called by muse, mutect2, varscan2
- KMT2C | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV51423187; called by muse, mutect2, varscan2
- KRT34 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV67449520; called by muse, mutect2, varscan2
- KRT72 | c.1310+1G>T p.X437_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV53373709; called by muse, mutect2, varscan2
- KRT79 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57939124; called by muse, mutect2, varscan2
- KRTAP1-5 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62624114; called by muse, mutect2, varscan2
- KRTAP10-7 | c.600C>A p.C200* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV59109811; called by muse, mutect2, varscan2
- L1TD1 | c.2493T>G p.F831L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV63133334; called by muse, mutect2, varscan2
- LAMA3 | c.2676A>T p.L892F | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58065785; called by muse, mutect2, varscan2
- LAP3 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as COSV56899293; called by muse, mutect2, varscan2
- LARS1 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV50973540; called by muse, mutect2, varscan2
- LCE1F | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57669032; called by muse, mutect2, varscan2
- LGALS13 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV55679692; called by muse, mutect2, varscan2
- LILRA1 | c.1040A>T p.Q347L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52179450; called by muse, mutect2, varscan2
- LILRB1 | c.1597C>A p.L533I (on ENST00000427581; = p.L483I on NM_006669.6) | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as COSV61116929, COSV61121346; called by muse, mutect2, varscan2
- LMNB1 | c.1639A>T p.K547* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV54397220; called by muse, mutect2, varscan2
- LMTK2 | c.3635G>T p.G1212V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV51992998; called by muse, mutect2, varscan2
- LRCH3 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as COSV58390534; called by muse, mutect2, varscan2
- LRCH3 | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV58390555; called by muse, mutect2, varscan2
- LRP1 | c.3601G>T p.G1201C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54506005; called by muse, mutect2, varscan2
- LRP1B | c.5263G>A p.G1755R | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.523); catalogued as COSV101261170, COSV67200981; called by muse, mutect2
- LRP2 | c.12150G>T p.E4050D | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55547057; called by muse, mutect2, varscan2
- LRP2 | c.5882C>T p.S1961F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55547067; called by muse, mutect2, varscan2
- LRPPRC | c.3241G>T p.D1081Y | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV53236255; called by muse, mutect2, varscan2
- LRRC15 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs267599743, COSV61649800; called by muse, mutect2, varscan2
- LRRC30 | c.474C>A p.C158* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV67301513; called by muse, mutect2, varscan2
- LRRC47 | c.852G>T p.R284S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV65562226; called by muse, mutect2
- LRRIQ3 | c.1852G>T p.V618F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1394842134; called by muse, mutect2, varscan2
- LRRK2 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54148418; called by muse, mutect2, varscan2
- LRRK2 | c.7185G>T p.E2395D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV54148433; called by muse, mutect2
- LSP1 | c.554T>A p.I185N | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV61133327; called by muse, mutect2, varscan2
- LUM | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 26/135 reads (19%) | catalogued as COSV57127483, COSV57127798; called by muse, mutect2, varscan2
- LUZP2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV61199878; called by muse, mutect2, varscan2
- MAGEA12 | c.322G>C p.A108P | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as COSV63294494; called by muse, mutect2, varscan2
- MAGEL2 | c.2636C>A p.P879Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV58566425; called by muse, mutect2, varscan2
- MALT1 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61934457; called by muse, mutect2, varscan2
- MAP1B | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV57096441; called by muse, mutect2, varscan2
- MAP2K1 | c.565A>T p.R189* | Nonsense Mutation (SNP) | VAF 25/148 reads (17%) | catalogued as COSV61069799; called by muse, mutect2, varscan2
- MAP3K5 | c.3334A>T p.K1112* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV62888205; called by muse, mutect2, varscan2
- MARCHF8 | c.793G>T p.G265* | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | catalogued as COSV60571491; called by muse, mutect2, varscan2
- MAS1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as COSV53120885; called by muse, mutect2, varscan2
- MASP1 | c.1963A>T p.R655* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV61825289; called by muse, mutect2, varscan2
- MASP2 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68896302; called by muse, mutect2, varscan2
- MBNL2 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV59119326; called by muse, mutect2, varscan2
- MC5R | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61254285; called by muse, mutect2, varscan2
- MCM4 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100031436, COSV50621591; called by muse, mutect2, varscan2
- MCPH1 | c.300A>T p.L100F | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs1305499761, COSV60911770; called by muse, mutect2, varscan2
- MED21 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV51460911; called by muse, mutect2, varscan2
- MEGF8 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52079298; called by muse, mutect2, varscan2
- MEGF8 | c.6899G>T p.R2300L (on ENST00000251268 / NM_001271938.2; = p.R2233L on NM_001410.3) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.357); catalogued as COSV52079312; called by muse, mutect2, varscan2
- MET | c.2583+1G>T p.X861_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | catalogued as COSV59259120; called by muse, mutect2, varscan2
- MEX3C | c.1825G>T p.V609L | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as COSV68529732; called by muse, mutect2, varscan2
- MFAP5 | c.59-1G>T p.X20_splice | Splice Site (SNP) | VAF 11/69 reads (16%) | catalogued as COSV63945161; called by muse, mutect2, varscan2
- MFSD1 | c.1361G>T p.R454I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV51839897; called by muse, mutect2
- MGAM | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72074193; called by muse, mutect2, varscan2
- MIB1 | c.1729G>C p.D577H | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55088731, COSV55089049; called by muse, mutect2, varscan2
- MICU3 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58845506; called by muse, mutect2, varscan2
- MIEF1 | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.989); catalogued as COSV57477651, COSV57478058; called by muse, mutect2, varscan2
- MLH3 | c.527A>T p.E176V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53134713; called by muse, mutect2, varscan2
- MMRN2 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV64400570; called by muse, mutect2, varscan2
- MON2 | c.1829A>T p.K610I | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54805265; called by muse, mutect2
- MORC3 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV68688070; called by muse, mutect2, varscan2
- MORN3 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62507158; called by muse, mutect2, varscan2
- MOSPD2 | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66859827; called by muse, mutect2, varscan2
- MPP1 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65728028, COSV65728091; called by muse, mutect2, varscan2
- MPP2 | c.1571G>T p.R524L (on ENST00000461854 / NM_001278372.2; = p.R500L on NM_005374.5) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV52233554, COSV52234595; called by muse, mutect2, varscan2
- MRC1 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs200635754, COSV99519558; called by muse, mutect2, varscan2
- MSANTD3 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV58491368, COSV58492022; called by muse, mutect2, varscan2
- MSH4 | c.788G>T p.S263I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV54199729; called by muse, mutect2, varscan2
- MSH4 | c.1230G>T p.T410= | Splice Region (SNP) | VAF 15/119 reads (13%) | catalogued as COSV54199753; called by muse, mutect2, varscan2
- MTG1 | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53371721; called by muse, mutect2, varscan2
- MUC16 | c.1276G>T p.G426* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as COSV67452487, COSV67467117; called by muse, mutect2, varscan2
- MUL1 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51641217; called by muse, mutect2, varscan2
- MYCBP2 | c.9712G>T p.G3238W (on ENST00000357337; = p.G3276W on NM_015057.5) | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62013975; called by muse, mutect2
- MYF6 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57351080; called by muse, mutect2, varscan2
- MYH13 | c.5554A>T p.K1852* | Nonsense Mutation (SNP) | VAF 81/165 reads (49%) | catalogued as COSV52823790; called by muse, mutect2, varscan2
- MYH13 | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52823803; called by muse, mutect2, varscan2
- MYH2 | c.5816G>A p.S1939N | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV55434626; called by muse, mutect2, varscan2
- MYH7 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.701); catalogued as COSV62517745; called by muse, mutect2, varscan2
- MYO10 | c.5039A>G p.K1680R | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.083); catalogued as COSV57019231; called by muse, mutect2, varscan2
- MYPN | c.3638C>T p.P1213L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1463415893, COSV62732542; called by muse, mutect2, varscan2
- NAA16 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65064751; called by muse, mutect2, varscan2
- NALCN | c.3763G>T p.E1255* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV51925975; called by muse, mutect2, varscan2
- NBN | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55372269; called by muse, mutect2, varscan2
- NCKAP1L | c.2202C>G p.I734M | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53202887, COSV53205074; called by muse, mutect2, varscan2
- NCKAP5 | c.490G>C p.V164L | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV58436101; called by muse, mutect2, varscan2
- NCOA1 | c.337G>T p.G113* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV56041646; called by muse, mutect2, varscan2
- NCOR2 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV62295823, COSV62300539; called by muse, mutect2, varscan2
- NDST1 | c.2567A>T p.N856I | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55785842; called by muse, mutect2, varscan2
- NECAB2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59419904, COSV59420156; called by muse, mutect2, varscan2
- NECTIN3 | c.916A>G p.R306G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60550505; called by muse, mutect2, varscan2
- NEDD4 | c.2764G>T p.D922Y (on ENST00000508342 / NM_001284338.1; = p.D503Y on NM_006154.4) | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59060244; called by muse, mutect2, varscan2
- NEO1 | c.4180A>C p.I1394L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56069310; called by muse, mutect2
- NFE2L2 | c.1241G>A p.S414N | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.156); catalogued as COSV67960703; called by muse, mutect2, varscan2
- NFU1 | c.485-1G>T p.X162_splice (on ENST00000410022 / NM_001002755.4; = p.X138_splice on NM_015700.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/61 reads (18%) | catalogued as COSV58006041; called by muse, mutect2, varscan2
- NIPSNAP2 | c.570G>T p.R190S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV59050687; called by muse, mutect2, varscan2
- NKG7 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV52467289, COSV52467956; called by muse, mutect2, varscan2
- NLGN4X | c.1800G>T p.L600F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV52010918; called by muse, mutect2, varscan2
- NLGN4X | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322970; called by muse, mutect2, varscan2
- NLGN4X | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52010954; called by muse, mutect2, varscan2
- NLRC3 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.452); catalogued as COSV57089118; called by muse, mutect2
- NLRP11 | c.2142C>A p.H714Q | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV64086456; called by muse, mutect2, varscan2
- NLRP12 | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60745387, COSV60756025; called by muse, mutect2, varscan2
- NLRP13 | c.2647G>C p.A883P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV61620906; called by muse, mutect2
- NLRP14 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV55065541; called by muse, mutect2, varscan2
- NLRP3 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV60221941, COSV60230061; called by muse, mutect2, varscan2
- NLRP3 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV60221947; called by muse, mutect2, varscan2
- NOBOX | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.339); catalogued as COSV56192528; called by muse, mutect2
- NOTCH1 | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039560; called by muse, mutect2, varscan2
- NOVA1 | c.1189G>T p.G397* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV57471406; called by muse, mutect2, varscan2
- NPEPL1 | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61938462; called by mutect2, varscan2
- NRXN3 | c.1301G>T p.G434V (on ENST00000335750 / NM_001330195.2; = p.G61V on NM_004796.6) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59730360; called by muse, mutect2
- NT5E | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390502643, COSV57627834; called by muse, mutect2, varscan2
- NTRK3 | c.2110G>T p.V704F | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62299619; called by muse, mutect2, varscan2
- NYNRIN | c.3956G>T p.R1319L | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as rs776363411, COSV66841711; called by muse, mutect2, varscan2
- OCM2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1293183009, COSV57535271; called by muse, mutect2, varscan2
- OLFM4 | c.202C>A p.Q68K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54576526; called by mutect2, varscan2
- OPRL1 | c.569C>A p.S190* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV61091232; called by muse, mutect2, varscan2
- OR10G4 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV57977159; called by muse, mutect2, varscan2
- OR10H4 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV59061484; called by muse, mutect2, varscan2
- OR10V1 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55696540; called by muse, mutect2, varscan2
- OR10W1 | c.331T>A p.Y111N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67720324; called by muse, mutect2
- OR1G1 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV61029997; called by muse, mutect2, varscan2
- OR1L8 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs149301014; called by muse, mutect2, varscan2
- OR2B11 | c.324C>A p.F108L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV59509742, COSV59511326; called by muse, mutect2, varscan2
- OR2L3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV63454865; called by muse, mutect2
- OR2L3 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 24/467 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV63454871; called by muse, mutect2
- OR2W3 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV64456475; called by muse, mutect2, varscan2
- OR4A16 | c.253T>G p.C85G | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.065); catalogued as COSV59042416; called by muse, mutect2, varscan2
- OR4K15 | c.781C>G p.R261G (on ENST00000305051; = p.R237G on NM_001005486.1) | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV59300834, COSV59301626, COSV59303559; called by muse, mutect2, varscan2
- OR51I2 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371546106, COSV99050328; called by muse, mutect2, varscan2
- OR52N2 | c.787A>T p.T263S | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV57676437; called by muse, mutect2
- OR56A4 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as COSV58109688; called by muse, mutect2, varscan2
- OR56A4 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV58109813; called by muse, mutect2, varscan2
- OR5D13 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV62333228; called by muse, mutect2, varscan2
- OR5K3 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV67349842; called by muse, mutect2, varscan2
- OR5M3 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV56566218; called by muse, mutect2, varscan2
- OR6C74 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.103); catalogued as rs769344888, COSV59605979; called by muse, mutect2, varscan2
- OR6C76 | c.184A>T p.R62W | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV60388840; called by muse, mutect2, varscan2
- OR6F1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.067); catalogued as COSV57467271; called by muse, mutect2, varscan2
- OR6T1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV58306236; called by muse, mutect2, varscan2
- OR6Y1 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV56928827; called by muse, mutect2, varscan2
- ORM1 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52278929; called by mutect2, varscan2
- OTOGL | c.2662G>A p.G888S (on ENST00000547103; = p.G879S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771111278; called by muse, mutect2, varscan2
- OTUD6A | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as COSV57972921; called by muse, mutect2, varscan2
- P2RY6 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as COSV62936030; called by muse, mutect2, varscan2
- PABPC5 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57039815; called by muse, varscan2
- PABPC5 | c.426C>A p.N142K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.406); catalogued as COSV57039828; called by muse, varscan2
- PABPC5 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV57039840; called by muse, mutect2, varscan2
- PACSIN3 | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54065597; called by muse, mutect2, varscan2
- PADI1 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV64938124; called by muse, mutect2, varscan2
- PADI3 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64934295; called by muse, mutect2, varscan2
- PADI3 | c.896C>A p.T299K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64934296; called by muse, mutect2, varscan2
- PAK2 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV59080248; called by muse, mutect2, varscan2
- PALD1 | c.136A>T p.S46C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54971949; called by muse, mutect2, varscan2
- PAMR1 | c.1335C>A p.I445= (on ENST00000619888 / NM_001001991.3; = p.I462= on NM_015430.4) | Splice Region (SNP) | VAF 13/75 reads (17%) | catalogued as COSV53510954; called by muse, mutect2
- PANK2 | c.1631G>C p.G544A (on ENST00000316562 / NM_153638.3; = p.G253A on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57253577; called by muse, mutect2, varscan2
- PASK | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs1021639110, COSV52150561; called by muse, mutect2, varscan2
- PAX1 | c.756C>A p.Y252* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV68271390; called by muse, mutect2, varscan2
- PCDHA3 | c.269T>A p.I90K | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV65365989; called by muse, mutect2, varscan2
- PCDHA6 | c.1624G>T p.V542L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.094); catalogued as COSV65343183, COSV65344643; called by muse, mutect2
- PCDHA7 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV65335623; called by muse, mutect2
- PCDHB13 | c.856T>A p.S286T | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.402); catalogued as COSV53394672; called by muse, varscan2
- PCDHB8 | c.826G>T p.G276* | Nonsense Mutation (SNP) | VAF 39/182 reads (21%) | catalogued as COSV50759467; called by muse, mutect2, varscan2
- PCDHB8 | c.2279C>G p.S760* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as rs1193550634, COSV50759473; called by muse, mutect2, varscan2
- PCDHGA5 | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); catalogued as COSV53898712, COSV53920522; called by muse, mutect2, varscan2
- PCDHGA5 | c.2137G>T p.V713L | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV53919738, COSV53920540; called by muse, mutect2, varscan2
- PCDHGB5 | c.2386C>A p.H796N | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV53918436, COSV53920558; called by muse, mutect2, varscan2
- PCNT | c.8795A>T p.K2932M | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV64026654; called by muse, mutect2, varscan2
- PCNX3 | c.4927G>T p.V1643F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV63135769; called by muse, mutect2, varscan2
- PCSK1 | c.2159T>A p.L720Q | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV60734514; called by muse, mutect2, varscan2
- PDCD11 | c.5075A>T p.K1692I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53294840; called by muse, mutect2, varscan2
- PDE1A | c.1173+1G>T p.X391_splice | Splice Site (SNP) | VAF 31/139 reads (22%) | catalogued as COSV59518861; called by muse, mutect2, varscan2
- PDE3A | c.2934A>T p.E978D | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV62970356; called by muse, mutect2, varscan2
- PDGFRA | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV57266570; called by muse, mutect2, varscan2
- PDZRN3 | c.1365C>A p.N455K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs953144011, COSV55194679; called by muse, mutect2, varscan2
- PDZRN3 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55194697, COSV55198902; called by muse, mutect2, varscan2
- PEX11A | c.702G>T p.M234I | Missense Mutation (SNP) | VAF 87/429 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55583168; called by muse, mutect2, varscan2
- PFDN1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 65/404 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV55836543; called by muse, mutect2, varscan2
- PGM2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs201598002, COSV101126599; called by muse, mutect2, varscan2
- PHF20L1 | c.1154A>C p.Q385P | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs999852737, COSV55190432; called by muse, mutect2, varscan2
- PIK3CG | c.1168G>T p.G390W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63247072; called by muse, mutect2, varscan2
- PIK3R4 | c.2088G>T p.M696I | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV63239937; called by muse, mutect2, varscan2
- PKD2L1 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58395258, COSV58398052; called by muse, mutect2
- PKHD1 | c.3559G>T p.G1187W | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV61867554; called by muse, mutect2, varscan2
- PKHD1L1 | c.5711C>G p.P1904R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV65740257, COSV65745416; called by muse, mutect2, varscan2
- PKP4 | c.1024G>T p.G342W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV67676396; called by muse, mutect2, varscan2
- PLA2G4F | c.490A>T p.S164C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV51826181; called by muse, mutect2
- PLCL1 | c.2216C>A p.A739D | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV70824196; called by muse, mutect2, varscan2
- PLCXD3 | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as COSV60606946, COSV60606965; called by muse, mutect2, varscan2
- PLEKHM1 | c.2147G>T p.R716M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV69598681; called by muse, mutect2, varscan2
- PLTP | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62464274; called by muse, mutect2, varscan2
- PLXNA1 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52524105, COSV52526230; called by muse, mutect2, varscan2
- PMFBP1 | c.2709-1G>T p.X903_splice (on ENST00000537465; = p.X898_splice on NM_031293.3) | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as rs745599842, COSV52822219; called by muse, mutect2, varscan2
- PNLDC1 | c.962+1G>A p.X321_splice | Splice Site (SNP) | VAF 11/95 reads (12%) | catalogued as COSV51704585; called by muse, mutect2, varscan2
- POLB | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV55345709; called by muse, mutect2, varscan2
- POLL | c.96A>T p.E32D | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV54574224; called by muse, mutect2, varscan2
- POLR1A | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs551886268, COSV55690938, COSV55693071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3A | c.1665G>T p.K555N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV64930653; called by muse, mutect2, varscan2
- POM121L12 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV68692590; called by muse, mutect2, varscan2
- POP1 | c.1822G>T p.G608C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62892272; called by muse, mutect2, varscan2
- PPP1R26 | c.2641G>C p.E881Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.764); catalogued as COSV63355126; called by muse, varscan2
- PPP1R26 | c.2766G>T p.Q922H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV63355134; called by muse, varscan2
- PPP2R2C | c.287A>T p.K96M | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV58671542; called by muse, mutect2, varscan2
- PRCP | c.566G>T p.R189M | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57288088; called by muse, mutect2, varscan2
- PRICKLE2 | c.2312C>T p.P771L (on ENST00000295902; = p.P715L on NM_198859.4) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.967); catalogued as COSV55764714; called by muse, mutect2, varscan2
- PRKCB | c.1690A>G p.M564V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV57772417; called by muse, mutect2, varscan2
- PRKCI | c.1307G>T p.W436L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55517558; called by muse, mutect2, varscan2
- PRKG1 | c.474G>C p.M158I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV64788391; called by muse, mutect2
- PRPF38B | c.1478G>T p.S493I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV64223624; called by muse, mutect2, varscan2
- PRSS33 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV53450549; called by muse, mutect2, varscan2
- PRUNE2 | c.6493G>A p.A2165T | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs774184369, COSV65039722; called by muse, mutect2, varscan2
- PRUNE2 | c.4795G>T p.V1599L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65039726; called by muse, mutect2, varscan2
- PRUNE2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs149982700, COSV65027098; called by muse, mutect2, varscan2
- PSG11 | c.1006T>A p.*336Kext*3 | Nonstop Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV60454467; called by muse, mutect2, varscan2
- PSG2 | c.43T>C p.W15R | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV68884217; called by muse, mutect2, varscan2
- PSKH2 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | catalogued as COSV52609858; called by muse, mutect2, varscan2
- PTPN14 | c.1261A>T p.M421L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.651); catalogued as COSV65282918; called by muse, mutect2
- PTPN22 | c.803A>T p.Q268L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63084630; called by muse, mutect2, varscan2
- PTPN22 | c.658A>T p.S220C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63084633; called by muse, mutect2, varscan2
- PTPN3 | c.588-1G>T p.X196_splice | Splice Site (SNP) | VAF 11/67 reads (16%) | catalogued as COSV52704345; called by muse, mutect2, varscan2
- PTPRE | c.210G>C p.R70S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.772); catalogued as rs761005798, COSV54548721; called by muse, mutect2, varscan2
- PTPRT | c.3952C>A p.R1318S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61958065, COSV61971663; called by muse, mutect2, varscan2
- PTPRT | c.2176+2T>A p.X726_splice | Splice Site (SNP) | VAF 18/105 reads (17%) | catalogued as COSV61971671; called by muse, mutect2, varscan2
- PTX4 | c.445G>C p.A149P (on ENST00000447419 / NM_001328608.2; = p.A144P on NM_001013658.1) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV53515031; called by muse, mutect2, varscan2
- PXDNL | c.2690C>A p.S897Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62483680; called by muse, mutect2, varscan2
- PXDNL | c.614A>T p.Q205L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62483692; called by muse, mutect2
- PYGM | c.2198A>G p.Y733C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as COSV51215525; called by muse, mutect2, varscan2
- QSER1 | c.2242G>T p.V748L (on ENST00000399302; = p.V877L on NM_001076786.3) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV67899977; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV51480459; called by muse, mutect2, varscan2
- RAB5A | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 104/189 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56083888; called by muse, mutect2, varscan2
- RABEP2 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 34/179 reads (19%) | catalogued as COSV62868894; called by muse, mutect2, varscan2
- RABGEF1 | c.577G>T p.E193* (on ENST00000439720 / NM_001287061.2; = p.E180* on NM_014504.3 and 29 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/116 reads (16%) | catalogued as COSV53161481, COSV53165848; called by muse, mutect2, varscan2
- RAD51B | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66845586; called by muse, mutect2, varscan2
- RALB | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV55602474; called by muse, mutect2, varscan2
- RANBP6 | c.2572T>C p.F858L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as COSV52388781; called by muse, mutect2, varscan2
- RBFOX1 | c.1154G>T p.S385I | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1414322007, COSV60952649; called by muse, mutect2, varscan2
- RBKS | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV56221149, COSV56222482; called by muse, mutect2, varscan2
- RBM43 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58878400; called by muse, mutect2, varscan2
- REG3A | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV59408988; called by muse, mutect2, varscan2
- RELN | c.3011C>A p.S1004Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58993494; called by muse, mutect2, varscan2
- RGS22 | c.2679C>A p.Y893* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | catalogued as COSV62659640; called by muse, mutect2, varscan2
- RGS6 | c.584A>T p.Q195L | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59570206; called by muse, mutect2, varscan2
- RGS7 | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as rs1307354409, COSV58535392; called by muse, mutect2, varscan2
- RHOB | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV55355806, COSV55356944; called by muse, mutect2, varscan2
- RIMS2 | c.3013C>A p.P1005T (on ENST00000666250 / NM_001348490.2; = p.P813T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV51667094, COSV51697222; called by muse, mutect2, varscan2
- RND3 | c.520T>G p.Y174D | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55723897; called by muse, mutect2, varscan2
- RNF20 | c.2771G>T p.C924F | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV66660664; called by muse, mutect2, varscan2
- RNGTT | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs778923275, COSV55648253; called by muse, mutect2, varscan2
- ROBO2 | c.1301C>G p.T434R | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59903793; called by muse, mutect2, varscan2
- ROBO2 | c.3854C>A p.P1285H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as COSV59903806; called by muse, mutect2, varscan2
- ROBO3 | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.119); catalogued as COSV67299334; called by muse, mutect2
- ROCK1 | c.2926G>T p.E976* | Nonsense Mutation (SNP) | VAF 17/127 reads (13%) | catalogued as COSV67695209; called by muse, mutect2, varscan2
- ROR2 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200058508; called by muse, mutect2, varscan2
- ROR2 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV65219381; called by muse, mutect2, varscan2
- RP1 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV55113552; called by muse, mutect2, varscan2
- RPS6KL1 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.924); catalogued as COSV63580879; called by muse, mutect2
- RRP9 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs750834054, COSV51753615; called by muse, mutect2, varscan2
- RSF1 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 86/266 reads (32%) | catalogued as COSV57836614, COSV57838115; called by muse, mutect2, varscan2
- RSPH6A | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55570855; called by muse, mutect2, varscan2
- RTN1 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV50720516, COSV50756194; called by muse, mutect2, varscan2
- RTTN | c.3888G>C p.L1296F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55343000; called by muse, mutect2, varscan2
- RUNX1T1 | c.265G>A p.G89S (on ENST00000265814 / NM_001198628.1; = p.G62S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV56141862, COSV56146631; called by muse, mutect2, varscan2
- RXFP2 | c.1002G>C p.L334= | Splice Region (SNP) | VAF 11/73 reads (15%) | catalogued as COSV53634179; called by muse, mutect2, varscan2
- RYR1 | c.3380G>T p.R1127L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.78); catalogued as CM112515, COSV62093331, COSV62094040; called by muse, mutect2
- RYR1 | c.5788A>T p.K1930* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV62093334; called by muse, mutect2, varscan2
- RYR2 | c.6320C>A p.T2107K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63669380; called by muse, mutect2, varscan2
- RYR2 | c.7711G>C p.V2571L | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV63675036; called by muse, mutect2
- RYR2 | c.12837G>T p.M4279I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV63675045; called by muse, mutect2, varscan2
- S1PR5 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV61013505; called by muse, mutect2, varscan2
- SAAL1 | c.605A>T p.K202M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55515025, COSV55515098; called by muse, mutect2, varscan2
- SACS | c.12712A>T p.S4238C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV66537497; called by mutect2, varscan2
- SALL1 | c.2515G>T p.D839Y | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV51755357; called by muse, mutect2, varscan2
- SALL1 | c.1066G>C p.V356L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV51755404; called by muse, mutect2, varscan2
- SAMD9 | c.1804T>G p.S602A | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1444435470, COSV66073912; called by muse, mutect2, varscan2
- SAXO2 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59753670; called by muse, mutect2, varscan2
- SBNO1 | c.2668-1G>T p.X890_splice (on ENST00000420886; = p.X889_splice on NM_018183.5) | Splice Site (SNP) | VAF 5/51 reads (10%) | catalogued as COSV57344962, COSV99929873; called by muse, mutect2, varscan2
- SC5D | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV50612787; called by muse, mutect2, varscan2
- SCAF4 | c.1737G>T p.W579C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54585422; called by muse, mutect2, varscan2
- SCD | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV64852966, COSV64853073; called by muse, mutect2, varscan2
- SCG3 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.098); catalogued as COSV55020554; called by muse, mutect2, varscan2
- SCML2 | c.1243C>G p.P415A | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV52619789; called by muse, mutect2, varscan2
- SCN11A | c.4075G>T p.V1359L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV56567930, COSV56568066; called by muse, mutect2, varscan2
- SCNN1B | c.1266C>A p.D422E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV56302927; called by muse, mutect2, varscan2
- SCUBE1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV51809353, COSV51809926, COSV51816866; called by muse, mutect2, varscan2
- SEC16A | c.4444G>T p.E1482* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV51524324; called by muse, mutect2
- SEC23IP | c.1235del p.G412Afs*13 | Frame Shift Del (DEL) | VAF 25/140 reads (18%) | catalogued as COSV64831312; called by mutect2, pindel, varscan2
- SEC24C | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as rs1454479442, COSV59540934; called by muse, mutect2, varscan2
- SEC31B | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64824665; called by muse, mutect2
- SELP | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as COSV55250055; called by muse, mutect2
- SEMA3A | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1376416723, COSV54865581; called by muse, mutect2
- SEMA4F | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV60282480; called by muse, mutect2, varscan2
- SENP5 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV60206702; called by muse, mutect2, varscan2
- SERPINB3 | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV52190515; called by muse, mutect2, varscan2
- SERPINB4 | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61984578, COSV61986361; called by muse, mutect2
- SETBP1 | c.2086C>A p.P696T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV56317071; called by muse, mutect2, varscan2
- SEZ6L | c.2294G>T p.R765L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50657839, COSV50660193; called by muse, mutect2, varscan2
- SFRP5 | c.847C>A p.R283S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV56603929; called by muse, mutect2, varscan2
- SGIP1 | c.2031+1G>C p.X677_splice | Splice Site (SNP) | VAF 15/121 reads (12%) | catalogued as COSV52765442; called by muse, mutect2, varscan2
- SH2D3C | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs748580820, COSV59120758; called by muse, varscan2
- SH3BP4 | c.2182A>T p.S728C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60643210; called by muse, mutect2, varscan2
- SH3KBP1 | c.1895G>C p.R632P | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV65646565; called by muse, mutect2
- SH3TC2 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1342015224, COSV60462124; called by muse, mutect2, varscan2
- SIGLEC11 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.49); catalogued as COSV70221923; called by muse, mutect2, varscan2
- SIPA1L1 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV62169296; called by mutect2, varscan2
- SKIL | c.913A>T p.M305L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV52058956; called by muse, mutect2, varscan2
- SKIL | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV52058972; called by muse, mutect2, varscan2
- SLAMF9 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 12/141 reads (9%) | catalogued as COSV100928146, COSV63636424; called by muse, mutect2
- SLC10A6 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV56721196, COSV56722447; called by muse, mutect2, varscan2
- SLC16A1 | c.205A>T p.M69L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.068); catalogued as COSV63708961; called by muse, mutect2, varscan2
- SLC18A3 | c.1483G>T p.D495Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV60322366; called by muse, mutect2
- SLC22A10 | c.1392C>A p.L464= | Splice Region (SNP) | VAF 18/142 reads (13%) | catalogued as COSV60420689; called by muse, mutect2, varscan2
- SLC26A5 | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV59699778; called by muse, mutect2
- SLC26A9 | c.1497-2A>T p.X499_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV61601669; called by muse, mutect2
- SLC28A2 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs867414560, COSV61663583; called by muse, mutect2, varscan2
- SLC2A14 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV61586046; called by muse, mutect2, varscan2
- SLC35C2 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.276); catalogued as COSV54756412, COSV54756657; called by muse, varscan2
- SLC39A6 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 16/133 reads (12%) | catalogued as COSV52368552, COSV99309478; called by muse, mutect2, varscan2
- SLC51A | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV53056829; called by muse, mutect2, varscan2
- SLC5A7 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50890131; called by muse, mutect2, varscan2
- SLC5A8 | c.862T>C p.W288R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV73310481; called by muse, mutect2, varscan2
- SLC6A2 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54915018; called by muse, mutect2, varscan2
- SLIT1 | c.4379G>T p.R1460L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as rs545410528, COSV56585870, COSV56590504, COSV56594678; called by mutect2, varscan2
- SLIT1 | c.985T>A p.F329I | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56585885; called by muse, mutect2, varscan2
- SLIT3 | c.2168C>A p.P723Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); catalogued as COSV60601280; called by muse, mutect2, varscan2
- SLITRK4 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62022861; called by muse, mutect2, varscan2
- SMARCA4 | c.3082-1G>T p.X1028_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV60790422; called by muse, mutect2, varscan2
- SMC3 | c.16-1G>T p.X6_splice | Splice Site (SNP) | VAF 9/75 reads (12%) | catalogued as COSV62419562; called by muse, mutect2, varscan2
- SMG7 | c.1323G>T p.Q441H | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV61630423; called by muse, mutect2, varscan2
- SMPD3 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54711234; called by muse, mutect2, varscan2
- SMURF1 | c.1454A>G p.H485R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62815867; called by muse, mutect2, varscan2
- SMYD1 | c.820T>A p.C274S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70224784; called by muse, mutect2, varscan2
- SNAPC3 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs765059045, COSV66402677; called by muse, mutect2, varscan2
- SND1 | c.2554G>T p.G852W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61238179; called by muse, mutect2, varscan2
- SORBS1 | c.2259G>T p.E753D (on ENST00000361941 / NM_001034954.2; = p.E500D on NM_024991.3 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53355216; called by muse, mutect2, varscan2
- SORCS3 | c.2741T>A p.V914E | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV63794166; called by muse, mutect2, varscan2
- SPATA31E1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57790492; called by muse, mutect2, varscan2
- SPATA31E1 | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.12); catalogued as rs757724889, COSV57790500; called by muse, mutect2, varscan2
- SPATS1 | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV55822437, COSV99913323; called by muse, mutect2, varscan2
- SPATS2L | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100660757; called by muse, mutect2
- SPDL1 | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.742); catalogued as COSV54667553; called by muse, mutect2, varscan2
- SPEF2 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.837); catalogued as COSV56795665; called by muse, mutect2, varscan2
- SPOCD1 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV57095248; called by muse, mutect2, varscan2
- SPOPL | c.1103C>A p.A368E | Missense Mutation (SNP) | VAF 81/430 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV54512733; called by muse, mutect2, varscan2
- SPRR2E | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.094); catalogued as COSV64203678; called by muse, mutect2, varscan2
- SPRR3 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54879105; called by muse, mutect2, varscan2
- SPTA1 | c.5092G>T p.V1698F | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100934324, COSV63750962; called by muse, mutect2, varscan2
- SPTA1 | c.2978C>A p.P993H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63750964, COSV63757529; called by muse, mutect2, varscan2
- SPTBN5 | c.6492G>T p.W2164C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV58018703; called by muse, mutect2, varscan2
- SRGAP1 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 25/136 reads (18%) | catalogued as COSV61896045; called by muse, mutect2, varscan2
- SRRM2 | c.3112G>T p.G1038* | Nonsense Mutation (SNP) | VAF 31/141 reads (22%) | catalogued as COSV57070750; called by muse, mutect2, varscan2
- ST6GAL2 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | PolyPhen benign (0.01); catalogued as COSV64527288, COSV64528515; called by mutect2, varscan2
- STAT4 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV61828890; called by muse, mutect2, varscan2
- STK38L | c.799A>T p.R267W | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV66520984; called by muse, mutect2, varscan2
- STPG1 | c.557A>T p.K186I (on ENST00000337248 / NM_001199013.2; = p.K139I on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV50218368; called by muse, mutect2, varscan2
- STX16 | c.463G>T p.G155W (on ENST00000371141 / NM_001001433.3; = p.G134W on NM_003763.6) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV56604806; called by muse, mutect2, varscan2
- STXBP5L | c.3418C>G p.R1140G | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV56507271; called by mutect2, varscan2
- SULF2 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV63415028, COSV63415199; called by muse, mutect2, varscan2
- SUPT20H | c.1753C>G p.L585V (on ENST00000350612 / NM_001014286.3; = p.L586V on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as COSV62247293; called by muse, mutect2, varscan2
- SYCN | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs764891208, COSV59212370; called by muse, mutect2, varscan2
- SYK | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV101002259, COSV65326378; called by muse, mutect2, varscan2
- SYNE1 | c.17965A>T p.S5989C (on ENST00000367255 / NM_182961.4; = p.S5918C on NM_033071.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV54942086; called by muse, mutect2, varscan2
- SYNE2 | c.4464A>C p.Q1488H | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV59944898; called by muse, mutect2, varscan2
- SYNGAP1 | c.2578G>C p.V860L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV53379686; called by muse, mutect2, varscan2
- SYNPO2 | c.2275G>C p.V759L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV61108516; called by muse, mutect2, varscan2
- SYT13 | c.1109A>T p.Q370L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV50072944; called by muse, mutect2, varscan2
- TAF3 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as COSV60204730; called by muse, mutect2, varscan2
- TAS1R2 | c.1608G>T p.Q536H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV64744245; called by muse, mutect2
- TAS2R38 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV71885217; called by muse, mutect2, varscan2
- TBX18 | c.925T>A p.Y309N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63737467; called by muse, mutect2
- TCEA1 | c.678G>A p.E226= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as rs963722279, COSV67172283; called by muse, mutect2, varscan2
- TCFL5 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53895928, COSV53897294; called by muse, mutect2
- TCN1 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.046); catalogued as COSV57252667; called by muse, mutect2, varscan2
- TEKT1 | c.93G>C p.R31S | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58622743; called by muse, mutect2, varscan2
- TENM3 | c.6348G>C p.E2116D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.935); catalogued as COSV69302999; called by muse, mutect2, varscan2
- TEX15 | c.1866C>A p.Y622* (on ENST00000256246; = p.Y1005* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | catalogued as COSV56343944; called by muse, mutect2, varscan2
- TEX35 | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV51104043, COSV51109662; called by muse, mutect2, varscan2
- TF | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV53919159; called by muse, mutect2, varscan2
- THNSL2 | c.691C>G p.Q231E | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59082394; called by muse, mutect2, varscan2
- THY1 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV52454069; called by muse, mutect2
- TIAM1 | c.2761G>T p.G921C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV54543709; called by muse, mutect2, varscan2
- TIMELESS | c.2803G>T p.G935W | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57510102; called by muse, mutect2, varscan2
- TLR1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs375985007; called by muse, mutect2, varscan2
- TLR4 | c.2515A>T p.I839F (on ENST00000355622 / NM_138554.5; = p.I799F on NM_003266.4) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as COSV62922789; called by muse, mutect2, varscan2
- TMC1 | c.237A>T p.A79= | Splice Region (SNP) | VAF 21/85 reads (25%) | catalogued as COSV52771898; called by muse, mutect2, varscan2
- TMEFF2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55830212, COSV55830780; called by muse, mutect2, varscan2
- TMEM171 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55129912; called by mutect2, varscan2
- TMEM177 | c.909G>T p.R303S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV55608412; called by muse, mutect2, varscan2
- TMEM270 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV57638321; called by muse, mutect2, varscan2
- TMEM94 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58594262; called by muse, mutect2, varscan2
- TMF1 | c.2565G>T p.R855S | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV68373929; called by muse, mutect2, varscan2
443 further variants in this file (157 protein-altering or splice-affecting, 258 silent, 28 other) are not listed here.
